Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3850, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3850-01A (Primary Tumor).

Diagnosis:

This is a partial resection sample of the colon (transverse colon) with a moderately to poorly differentiated adenocarcinoma with a histopathological differentiation grade G2-3, with erosions of the inner tumor surface, with peritumorous chronic recurrent secondary inflammation with an acute inflammatory flare, with carcinomatous lymphangitis, with tumor infiltration of the colon wall layers as far as the tunica muscularis,

with moderate chronic lymphadenitis of the tumor-free lymph nodes (0/15) and with tumor-free overview slices from all other parts of the resection material described

According to the section preparations available, the tumor spread of the colon carcinoma correspond to the tumor stage pT2, pN0 (0/15), Mx, L1, R0.

Tumor classification:

ICDO-DA-M 8140/3, G2-3

10+

Source: NCI Genomic Data Commons file d0faa7b1-b8ef-4439-aba6-ef0c6fc42635 (TCGA-AA-3850.4B03559C-8668-46B0-9611-063D346FD54C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).